Somatic mutation profile of tumor specimen 0DW42G from CCDI case PBCNTR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,467 days).
Specimen 0DW42G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dad198f1-0e8f-4e99-82d2-05ba03b587dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW41T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecf8ef7f-a732-45d8-a9c8-1c0cccee51b5

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IVL | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 91/308 reads (30%) | catalogued as rs780252658; called by muse, mutect2, varscan2
- KLF16 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs1253660958; called by muse, mutect2
- MMRN1 | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 31/573 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs749675073, COSV53336528; called by muse, mutect2
- PXDN | c.2422G>C p.V808L | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV99412622; called by muse, mutect2, varscan2
- ARX | c.1532C>A p.A511E | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CRYBG3 | c.2970A>C p.L990F | Missense Mutation (SNP) | VAF 17/599 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.222); called by muse, mutect2
- KCTD13 | c.161C>G p.T54S | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2
- PRLR | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 62/822 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- COL1A2 | c.2566-57A>G | Intron (SNP) | VAF 20/101 reads (20%) | called by mutect2, varscan2
- RAB12 | c.427-60C>T | Intron (SNP) | VAF 84/255 reads (33%) | catalogued as COSV61399325; called by muse, mutect2, varscan2
- SMCO2 | c.601-47G>A | Intron (SNP) | VAF 75/114 reads (66%) | called by muse, mutect2, varscan2
